Somatic mutation profile of tumor specimen TARGET-40-NAAHBP-02A (aliquot TARGET-40-NAAHBP-02A-01D) from TARGET case TARGET-40-NAAHBP, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.0 years (4,747 days).
Specimen TARGET-40-NAAHBP-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a2eb485-7fb7-489a-87cd-457bc5afdfb7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHBP-10A (Blood Derived Normal), aliquot TARGET-40-NAAHBP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dba1630-8d57-498b-acb7-cd0faaf8c98a

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.2801C>G p.P934R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221235046; called by muse, mutect2, varscan2
- CNTNAP2 | c.3176A>T p.K1059M | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV62149917; called by muse, mutect2
- DEPDC5 | c.3843T>A p.N1281K (on ENST00000400246; = p.N1350K on NM_014662.5) | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.51); called by muse, mutect2
- DMD | c.2516T>A p.L839Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ENTPD4 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- PRKACG | c.323A>T p.Q108L | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLIT3 | c.3662G>T p.S1221I | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- CCDC33 | c.930C>A p.G310= | Silent (SNP) | VAF 25/235 reads (11%) | catalogued as COSV58355980; called by muse, mutect2, varscan2
- CHD9 | c.6903G>A p.L2301= | Silent (SNP) | VAF 18/145 reads (12%) | called by muse, mutect2, varscan2
- DGKG | c.1614C>A p.G538= | Silent (SNP) | VAF 46/126 reads (37%) | called by muse, mutect2, varscan2
- HUWE1 | c.12504A>T p.L4168= | Silent (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- PKHD1 | c.5013C>G p.T1671= | Silent (SNP) | VAF 28/430 reads (7%) | catalogued as COSV61860782; called by muse, mutect2
- MYCBPAP | c.-83_-61del | 5'UTR (DEL) | VAF 18/47 reads (38%) | called by mutect2, varscan2
- TTN | c.10360+2224C>T | Intron (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
